Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3444, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3444-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: Left Renal Mass

Source of Specimen(s):
Left kidney

Gross Description:
Received in one part.
Source of Tissue: 1. Labeled #1, "left kidney"

Gross Description: Received fresh labeled, left kidney" is a 403 gram left nephrectomy having a moderate amount of attached perinephric fat. There is a 5.0 x 0.3 cm fragment of attached ureter having a lumen, 0.2 cm which is patent to the hilum. The kidney itself is 11.0 x 4.5 x 4.5 cm in greatest dimension. It is bivalved to reveal red-purple renal parenchyma having a well-defined cortico-medullary junction. In the mid to lower pole there is a 6.0 x 3.5 x 3.0 cm mass having golden-yellow-orange soft lobulated cut surfaces with irregular borders. There is a 0.8 x 0.6 cm fragment of unremarkable adrenal gland. Representative sections are submitted in eight blocks.

Designation of Sections: A- ureter and vascular margins, B-C- tumor with inked circumferential margin, D-F- additional tumor, G- random section kidney, H- adrenal gland

Summary of Sections: multiple
Note: Tissue is submitted for Cytogenetic Studies.

Final Diagnosis:

1. Left kidney and portion of adrenal gland, radical nephrectomy and partial adrenalectomy:
- Renal cell carcinoma, clear cell type, 6.0 cm, Fuhrman nuclear grade II/IV.
- Tumor is limited to renal parenchyma.
- No angiolymphatic invasion seen.
- Renal vascular margin, ureteral margin and perirenal margin are free of tumor.
- Adrenal gland, no tumor seen.
- pT1bNxMx
-

[page 2 of 2]
FCGTL: Chromo15, Chrom45, Interp

Results-Comments

CYTOGENETIC ANALYSIS REPORTS

DIAGNOSIS: Left Renal Mass

KARYOTYPE: Abnormal mosaic [REDACTED] karyotype:
31,XX,del(3)(p21p25),der(3)t(3;5)(p13;q13),inc[1]/76
82<4n>,
idemx2,+2,+2,inc[cp3]/46,XX[4]

RESULTS: The renal mass was harvested after eleven and fourteen days in culture. Four metaphases were found in a scan of six slides from the eleven-day culture. All four cells had an abnormal karyotype with a deletion in the p arm of chromosome 3 and a derivative chromosome consisting of a portion of chromosome 3 attached to part of the q arm of chromosome 5. The derivative chromosome resulted in loss of part of the p arm of chromosome 3. Three of the cells were polyploid, and one of the cells was a broken cell. Loss of the p arm of chromosome 3 has been reported in clear cell renal carcinoma.

Only four cells were found in a scan of four slides from the fourteen-day culture. All four cells had a normal karyotype which could reflect an overgrowth of normal interstitial tissue rather than tumor. A preliminary report was given to [REDACTED]

Source: NCI Genomic Data Commons file e5ee7c09-de59-4cea-b4d7-aa70ca29fc97 (TCGA-AK-3444.81695A84-9C99-4EC9-A2F4-AB0A62764EB3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).